Somatic mutation profile of tumor specimen TCGA-RN-AAAQ-01A (aliquot TCGA-RN-AAAQ-01A-21D-A38Z-09) from TCGA case TCGA-RN-AAAQ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 52.4 years (19,123 days).
Specimen TCGA-RN-AAAQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be1b45fe-565c-4301-aaa2-21c3c34cfd71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RN-AAAQ-10A (Blood Derived Normal), aliquot TCGA-RN-AAAQ-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dd79922-c05a-4aee-8be5-086705981c09

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Splice Site 2, Nonsense Mutation 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKLE1 | c.1828G>A p.E610K (on ENST00000394458; = p.E556K on NM_152363.6) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs766333087, COSV101082493; called by muse, mutect2, varscan2
- C6 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs765761929, COSV99667669; called by muse, mutect2, varscan2
- CACNG8 | c.136T>G p.Y46D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99555132; called by muse, mutect2, varscan2
- CHAF1A | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100011430, COSV56671911; called by muse, mutect2, varscan2
- CHST8 | c.828C>G p.N276K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52857940, COSV99381548; called by muse, mutect2, varscan2
- COL28A1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.103); catalogued as COSV101258894; called by muse, mutect2, varscan2
- COPS4 | c.714A>T p.A238= | Splice Region (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100018803, COSV52317650; called by muse, mutect2, varscan2
- DGKK | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.146); catalogued as COSV101053179; called by muse, mutect2, varscan2
- FAM83C | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs776231191, COSV100981682; called by mutect2, varscan2
- FMR1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV99503727; called by muse, mutect2
- GALNT17 | c.1001G>T p.R334M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100354641, COSV100355843; called by muse, mutect2, varscan2
- GRIP1 | c.876T>A p.C292* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99670731; called by muse, mutect2
- HTR2A | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as rs757096279, COSV101096811; called by muse, mutect2, varscan2
- IL21R | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100560480; called by muse, mutect2, varscan2
- KLHL28 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as rs755300344, COSV61888587; called by muse, mutect2, varscan2
- METTL9 | c.542G>T p.W181L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV100820621; called by muse, mutect2, varscan2
- MTCL1 | c.4639G>T p.G1547* (on ENST00000306329 / NM_001378206.1; = p.G1228* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | catalogued as COSV100095427; called by muse, mutect2, varscan2
- NCAN | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs564014772, COSV53052691; called by muse, mutect2, varscan2
- PER1 | c.2318A>G p.Y773C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs772045908, COSV100424811; called by muse, mutect2, varscan2
- PRKD1 | c.2527C>G p.Q843E | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100121386; called by muse, mutect2
- RIPK1 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99454308; called by muse, mutect2, varscan2
- ROCK1 | c.3592-2A>C p.X1198_splice | Splice Site (SNP) | VAF 4/66 reads (6%) | catalogued as COSV101296599; called by muse, mutect2
- RTEL1 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV100542768; called by muse, mutect2
- SDK1 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs377301442; called by muse, mutect2, varscan2
- SLC4A4 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.336); catalogued as rs757623063, COSV99141893; called by muse, mutect2, varscan2
- SYN2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99826091; called by muse, mutect2, varscan2
- TBPL1 | c.14G>C p.S5T | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV99393947; called by muse, mutect2, varscan2
- THOC5 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745803082, COSV100803647; called by muse, mutect2, varscan2
- ZNF443 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV100042326; called by muse, mutect2, varscan2
- ZNF776 | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100414325; called by muse, mutect2, varscan2
- GPR37L1 | c.616_630+1del p.X206_splice | Splice Site (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- MCL1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2
- FLRT2 | c.735T>C p.P245= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100420912; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.18G>A p.R6= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs747497403; called by muse, mutect2, varscan2
- NR3C2 | c.1614G>A p.S538= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs146153919, COSV60993997; called by muse, mutect2, varscan2
- PRDM14 | c.228C>A p.P76= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV99400467; called by muse, mutect2
- SLC5A3 | c.1692A>G p.P564= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100758047; called by muse, mutect2, varscan2
- ZNF638 | c.4458A>C p.I1486= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100039711; called by muse, mutect2, varscan2
- BTBD11 | c.1491-184G>A | Intron (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99776826; called by muse, mutect2, varscan2
